CCDI case PBCHWV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cfcd93b9-6dd8-4beb-b3a2-562078be05dc

Demographics
Sex at birth: female.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,112 days).

Biospecimens (1 sample)
- Sample 0DSI9G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
